Somatic mutation profile of tumor specimen TCGA-S7-A7X1-01A (aliquot TCGA-S7-A7X1-01A-11D-A35I-08) from TCGA case TCGA-S7-A7X1, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 23.1 years (8,426 days).
Specimen TCGA-S7-A7X1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4e44d9c-2406-444c-ae76-5c9b60f85a59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S7-A7X1-10A (Blood Derived Normal), aliquot TCGA-S7-A7X1-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb81d5ad-5490-4eb6-a99f-546631550a79

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADH6 | c.1042A>C p.T348P | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV99422348; called by muse, varscan2
- KIAA1217 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.49); catalogued as rs147538283; called by muse, mutect2, varscan2
- PCLO | c.9541G>C p.V3181L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV61662050, COSV99067640; called by muse, mutect2, varscan2
- ADH6 | c.1043C>T p.T348I | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, varscan2
- MUC16 | c.17951C>A p.P5984Q | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- GATB | c.16C>T p.L6= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs553313362, COSV56133154; called by mutect2, varscan2
